Somatic mutation profile of tumor specimen 0DN1D2 from CCDI case PBCAXL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,099 days).
Specimen 0DN1D2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d726152-15a6-4b21-8c22-f34d3984c841.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff7b511c-6621-48c7-bf5a-dacc4758c4a8

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 5 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Intron 6, Silent 5, 3'UTR 2, RNA 2, 5'Flank 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPT4 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 455/981 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242969144, COSV67921340; called by muse, mutect2, varscan2
- DSEL | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 144/1109 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); catalogued as COSV59491747; called by muse, mutect2, varscan2
- FAT2 | c.6089G>A p.R2030Q | Missense Mutation (SNP) | VAF 494/539 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs145039507; called by muse, mutect2, varscan2
- FMO2 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 423/906 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1459662027; called by muse, mutect2, varscan2
- IRX1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 600/2124 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs764067065; called by muse, mutect2, varscan2
- KRT79 | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 215/502 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as rs770946783; called by muse, mutect2, varscan2
- LY75 | c.1588C>A p.L530M | Missense Mutation (SNP) | VAF 115/681 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038830358, COSV55107854; called by muse, mutect2, varscan2
- NPTX2 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 288/905 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201822467; called by muse, mutect2, varscan2
- PKDREJ | c.2663C>A p.T888K | Missense Mutation (SNP) | VAF 558/1160 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99478268; called by muse, mutect2, varscan2
- RAD21 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 542/1764 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52055974; called by muse, mutect2, varscan2
- SPRTN | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 78/890 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50478708; called by muse, mutect2
- TAF1 | c.3296G>A p.R1099H (on ENST00000373790 / NM_138923.4; = p.R1120H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 644/721 reads (89%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as rs371501141; called by muse, mutect2, varscan2
- TLR2 | c.1726C>A p.Q576K | Missense Mutation (SNP) | VAF 105/633 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52607189; called by muse, mutect2, varscan2
- TRPM8 | c.1399A>G p.I467V | Missense Mutation (SNP) | VAF 77/1207 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs201369256; called by muse, mutect2
- USP17L10 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.782); catalogued as rs761896168; called by muse, mutect2, varscan2
- ZP4 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 205/1153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63911289; called by muse, mutect2, varscan2
- BEST2 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 71/858 reads (8%) | called by muse, mutect2
- BRINP2 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 176/1313 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 58/1695 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- COX14 | c.108C>A p.H36Q | Missense Mutation (SNP) | VAF 420/878 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DENND1A | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 107/1227 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- FBLN7 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 128/731 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GABRB2 | c.1021G>C p.A341P | Missense Mutation (SNP) | VAF 712/788 reads (90%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- HELZ | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 150/1309 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 59/1984 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IL4 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 536/1854 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- KLK12 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 131/1118 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPO | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 95/802 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5AC | c.12965G>A p.S4322N | Missense Mutation (SNP) | VAF 212/499 reads (42%) | SIFT tolerated (0.19); called by muse, mutect2, varscan2
- MYBPC1 | c.2086G>T p.A696S (on ENST00000550270 / NM_206820.2; = p.A721S on NM_002465.4) | Missense Mutation (SNP) | VAF 198/1481 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYCBP2 | c.6170A>G p.E2057G (on ENST00000357337; = p.E2095G on NM_015057.5) | Missense Mutation (SNP) | VAF 190/1403 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NRL | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 88/954 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- PARP6 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 263/599 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIGT | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 252/515 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKP3 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 270/534 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PTCH1 | c.2894C>A p.A965E | Missense Mutation (SNP) | VAF 242/1950 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.188); called by mutect2, varscan2
- RASGRF2 | c.2891C>A p.A964D | Missense Mutation (SNP) | VAF 666/2338 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RGL3 | c.372-3C>A | Splice Region (SNP) | VAF 82/715 reads (11%) | called by muse, mutect2, varscan2
- RSBN1 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 37/906 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- SLC25A43 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 102/374 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SOGA1 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 454/959 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- STK36 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 158/1019 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMC3 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 297/650 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TRIM39 | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 206/1239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM52 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 330/355 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ZSCAN1 | c.1112T>C p.V371A | Missense Mutation (SNP) | VAF 325/627 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID3A | c.1377G>A p.P459= | Silent (SNP) | VAF 70/573 reads (12%) | catalogued as rs752144558, COSV99708376; called by muse, mutect2, varscan2
- CLTCL1 | c.4452C>T p.I1484= | Silent (SNP) | VAF 268/576 reads (47%) | catalogued as rs782618837, COSV54239350; called by muse, varscan2
- KLHL22 | c.577T>C p.L193= | Silent (SNP) | VAF 198/421 reads (47%) | catalogued as rs368788549; called by muse, mutect2, varscan2
- PPFIA1 | c.909A>G p.K303= | Silent (SNP) | VAF 161/1191 reads (14%) | called by muse, mutect2, varscan2
- RNASEH2A | c.528T>C p.S176= | Silent (SNP) | VAF 408/882 reads (46%) | catalogued as rs1419883149; called by muse, mutect2, varscan2
- AC114316.1 | n.1488A>C | RNA (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- CPNE8 | c.1433-9C>A | Intron (SNP) | VAF 88/810 reads (11%) | called by muse, mutect2, varscan2
- FAAP20 | chr1:2198744 C>A | 5'Flank (SNP) | VAF 356/386 reads (92%) | called by muse, mutect2, varscan2
- FLII | c.63+147C>T | Intron (SNP) | VAF 100/666 reads (15%) | called by muse, mutect2, varscan2
- NRDC | c.1824-25C>A | Intron (SNP) | VAF 366/402 reads (91%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.913+28A>T | Intron (SNP) | VAF 339/775 reads (44%) | called by muse, mutect2, varscan2
- TEAD1 | c.330+94G>A | Intron (SNP) | VAF 35/140 reads (25%) | catalogued as rs1448773557; called by muse, mutect2, varscan2
- TMEM105 | n.562G>T | RNA (SNP) | VAF 373/820 reads (45%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.*295C>A | 3'UTR (SNP) | VAF 54/157 reads (34%) | called by muse, mutect2, varscan2
- UBE3D | c.*82C>A | 3'UTR (SNP) | VAF 20/560 reads (4%) | called by muse, mutect2
- ZNF557 | c.32-17G>T | Intron (SNP) | VAF 73/510 reads (14%) | called by muse, mutect2, varscan2
